Somatic mutation profile of tumor specimen TCGA-CD-5800-01A (aliquot TCGA-CD-5800-01A-11D-1600-08) from TCGA case TCGA-CD-5800, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G1.
Specimen TCGA-CD-5800-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 830c64c4-07df-469f-82e7-e2b169491924.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-5800-10A (Blood Derived Normal), aliquot TCGA-CD-5800-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16eec41b-8549-4b33-9798-78a707b220d7

The open-access MAF lists 163 somatic variants for this specimen: 127 protein-altering or splice-affecting, 36 silent.
By variant classification: Missense Mutation 117, Silent 36, Frame Shift Ins 4, Nonsense Mutation 2, Splice Region 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPC1 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376213990, CM032629; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.202T>G p.F68V | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV50984030; called by muse, mutect2
- ABHD16B | c.447C>G p.D149E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs764669489, COSV53863382, COSV53864155; called by muse, mutect2, varscan2
- AC006059.2 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as rs747462890, COSV59608180; called by muse, mutect2, varscan2
- ADAM23 | c.1358C>A p.T453K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.088); catalogued as COSV52221324; called by muse, mutect2, varscan2
- ADAP1 | c.428A>C p.N143T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV56215546; called by muse, mutect2, varscan2
- ALG10B | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs570861653, COSV58143926; called by muse, mutect2, varscan2
- ANKRD11 | c.2579C>T p.S860L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs145730800; called by muse, mutect2
- ARAP2 | c.4901A>C p.N1634T | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV58289211; called by muse, mutect2, varscan2
- ART1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51705691; called by muse, mutect2, varscan2
- ASPM | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV54130068, COSV54133510; called by muse, mutect2, varscan2
- B4GALNT1 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.505); catalogued as COSV57543719; called by muse, mutect2, varscan2
- BMP2K | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV58597037; called by muse, mutect2, varscan2
- BORCS8-MEF2B | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as rs766141253, COSV50767126; called by mutect2, varscan2
- C22orf31 | c.154A>G p.N52D | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV53310866; called by muse, mutect2, varscan2
- C3 | c.1126G>C p.V376L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV55576393; called by muse, mutect2, varscan2
- CCDC151 | c.204C>A p.H68Q | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV52952578; called by muse, mutect2
- CCNB3 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs781972354, COSV52076512; called by muse, mutect2
- CCNH | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV56925551; called by muse, mutect2, varscan2
- CD164 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV51533914, COSV51534058; called by muse, mutect2
- CDHR3 | c.1538G>C p.W513S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100489006, COSV58419223; called by muse, mutect2, varscan2
- CEP350 | c.2509A>C p.S837R | Missense Mutation (SNP) | VAF 17/253 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV62605891; called by muse, mutect2
- CFAP251 | c.2229C>G p.S743R | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV56612934; called by muse, mutect2
- CHD7 | c.6665A>G p.E2222G | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); catalogued as COSV71112691; called by muse, mutect2, varscan2
- CHMP2A | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 10/117 reads (9%) | catalogued as COSV53397382; called by muse, mutect2
- CHRFAM7A | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs527713019, COSV100241492; called by mutect2, varscan2
- CLIP1 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV56804965; called by muse, mutect2
- COG4 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs367766027, COSV99851375; called by muse, mutect2
- COQ6 | c.1279A>G p.T427A | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs150656371; called by muse, mutect2
- CPT1A | c.693C>T p.Y231= | Splice Region (SNP) | VAF 6/62 reads (10%) | catalogued as rs146551320, COSV55754285; ClinVar: likely benign; called by muse, mutect2
- CST6 | c.446T>A p.M149K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV56412003; called by muse, mutect2, varscan2
- CXorf58 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs761720174, COSV64858330; called by muse, mutect2, varscan2
- DCAF12L2 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs753211274, COSV100758778; called by muse, varscan2
- DDB1 | c.2665C>T p.R889W | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57104294; called by muse, mutect2, varscan2
- DDI1 | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.543); catalogued as COSV56385117; called by muse, mutect2, varscan2
- DHX58 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367980454; called by muse, varscan2
- DLGAP4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs374922768, COSV59420286; called by muse, mutect2, varscan2
- DSCAM | c.1763G>A p.S588N | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV68031111; called by muse, mutect2
- EDNRB | c.328G>A p.G110S (on ENST00000377211 / NM_001201397.1; = p.G20S on NM_000115.5) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs762469442, COSV57525391; called by muse, mutect2
- EEPD1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54201003; called by muse, mutect2, varscan2
- ELMO1 | c.84dup p.P29Tfs*11 | Frame Shift Ins (INS) | VAF 30/190 reads (16%) | catalogued as rs766966664; called by mutect2, varscan2
- EP400 | c.5483G>A p.G1828D | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.036); catalogued as COSV57778322; called by muse, mutect2, varscan2
- EPHA5 | c.392A>C p.K131T | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV56657172; called by muse, mutect2
- EPHB1 | c.1160C>T p.T387M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs56396912; called by muse, mutect2, varscan2
- FAM161B | c.727C>T p.R243C (on ENST00000651776; = p.R180C on NM_152445.3) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760681815, COSV54102817; called by mutect2, varscan2
- FAM53A | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57402321; called by muse, mutect2
- FREM2 | c.5068G>A p.D1690N | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54833032; called by muse, mutect2, varscan2
- GBF1 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100890629; called by muse, mutect2
- GNAS | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs1334915421, COSV58340510; called by muse, mutect2
- GRIK5 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.802); catalogued as rs779636580, COSV53476070; called by muse, mutect2, varscan2
- HIBADH | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.021); catalogued as COSV55315139; called by muse, mutect2, varscan2
- HPS1 | c.1580G>A p.R527K | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57268975; called by muse, mutect2, varscan2
- HSPG2 | c.1615C>A p.Q539K | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101012984; called by muse, mutect2
- KCNJ3 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423236044, COSV54539798; called by mutect2, varscan2
- KCNK9 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs753797613, COSV57283164; called by muse, mutect2, varscan2
- KDM6B | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1253485830, COSV54683988; called by muse, mutect2, varscan2
- LAMA5 | c.3532G>A p.E1178K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs374668224; called by muse, mutect2, varscan2
- LAYN | c.307G>T p.D103Y (on ENST00000375615 / NM_001258390.1; = p.D95Y on NM_178834.5) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65105131; called by muse, mutect2, varscan2
- LIN7C | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.02); catalogued as COSV53416070; called by muse, mutect2, varscan2
- LMO7 | c.591C>G p.S197R (on ENST00000357063; = p.S212R on NM_005358.5) | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100413760; called by muse, mutect2
- LONRF2 | c.1484C>A p.A495E | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66541407; called by muse, mutect2, varscan2
- LRFN5 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53266262; called by muse, mutect2, varscan2
- MAGI3 | c.845_846insA p.F282Lfs*2 | Frame Shift Ins (INS) | VAF 11/69 reads (16%) | catalogued as COSV100290058; called by mutect2, pindel, varscan2
- MAP4 | c.2406G>T p.K802N | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV53139924; called by muse, mutect2, varscan2
- METTL14 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs370370248, COSV66310834; called by muse, mutect2, varscan2
- MICAL2 | c.1045T>A p.Y349N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV56322781; called by muse, mutect2, varscan2
- MMP28 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs1012437556; called by muse, mutect2, varscan2
- NCAPG | c.535G>C p.V179L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV52271396; called by muse, mutect2, varscan2
- NLGN1 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64340198; called by muse, mutect2, varscan2
- NQO1 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57732242; called by muse, mutect2, varscan2
- OR13C4 | c.401T>C p.I134T | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs760078998, COSV52927633; called by muse, mutect2
- OR4N2 | c.220T>G p.S74A | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV60052993; called by muse, mutect2
- OXSM | c.923C>G p.S308* | Nonsense Mutation (SNP) | VAF 6/107 reads (6%) | catalogued as COSV99772101; called by muse, mutect2
- PCDH7 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs1169584528; called by muse, mutect2, varscan2
- PCDHB6 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs781940602, COSV50691167; called by muse, mutect2
- PCDHGA3 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53984954; called by muse, mutect2, varscan2
- PCDHGA6 | c.2333C>T p.T778M | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.105); catalogued as rs1450125576, COSV53984974; called by muse, mutect2, varscan2
- PGC | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs922411548, COSV63123320; called by muse, mutect2, varscan2
- PIK3CA | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV55891897; called by muse, mutect2
- PIK3CG | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs766854286, COSV63245615; called by mutect2, varscan2
- PLXNB3 | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs782236263, COSV62797243; called by muse, mutect2, varscan2
- PPM1B | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV56766932, COSV56768197; called by muse, mutect2
- PROM2 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV58299473; called by muse, mutect2
- PROS1 | c.193A>G p.K65E | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62399043; called by muse, mutect2, varscan2
- PTPRM | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 53/75 reads (71%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV59869807; called by muse, mutect2, varscan2
- PTPRM | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV100154654, COSV59848075; called by muse, mutect2
- RP1 | c.2675C>T p.A892V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV55121233, COSV55124738; called by muse, mutect2
- RPA1 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1455082802, COSV54609970; called by muse, mutect2, varscan2
- RUFY2 | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV66252904; called by muse, mutect2
- RUNDC1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64512170; called by muse, mutect2, varscan2
- S100PBP | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV63140342; called by muse, mutect2
- SCN1A | c.5959G>A p.D1987N (on ENST00000303395 / NM_001202435.3; = p.D1976N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV57677852; called by muse, mutect2, varscan2
- SEC16A | c.6390G>A p.S2130= | Splice Region (SNP) | VAF 4/25 reads (16%) | catalogued as rs1255161099, COSV51533640; called by muse, mutect2, varscan2
- SHH | c.737A>G p.D246G | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as rs1416459058, COSV51919482; called by muse, mutect2
- SLC9A5 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.449); catalogued as COSV55363338; called by muse, mutect2, varscan2
- SLCO1C1 | c.1833G>C p.L611F | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV56875809, COSV99859850; called by muse, mutect2, varscan2
- SPON2 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV52055754; called by muse, mutect2, varscan2
- SPTY2D1 | c.1169C>A p.T390K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV60474581; called by muse, mutect2, varscan2
- SSTR3 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs570846487, COSV60729839; called by muse, mutect2, varscan2
- STYXL2 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748897144, COSV54801697, COSV99608439; called by muse, mutect2, varscan2
- SURF2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as COSV64332504; called by muse, mutect2, varscan2
- SYNE1 | c.19766G>C p.S6589T (on ENST00000367255 / NM_182961.4; = p.S6518T on NM_033071.3) | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV99575069; called by muse, mutect2
- SYNE1 | c.16112G>A p.R5371Q (on ENST00000367255 / NM_182961.4; = p.R5300Q on NM_033071.3) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs527462104, COSV55034205, COSV55051690; called by muse, mutect2
- TAS2R4 | c.595C>A p.L199I | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV56093830; called by muse, mutect2, varscan2
- TCF20 | c.933G>T p.Q311H | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100166845; called by muse, mutect2
- TERT | c.2689G>A p.V897M | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs559028617, COSV57226456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEX47 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV51879511; called by muse, mutect2, varscan2
- THSD1 | c.1755C>G p.F585L | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51630054, COSV99319198; called by muse, mutect2, varscan2
- TMEM248 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.225); catalogued as rs1243252793, COSV58577876; called by muse, mutect2, varscan2
- TPTE | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs751216471; called by muse, mutect2, varscan2
- TRHDE | c.2951A>T p.N984I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV53853970; called by muse, mutect2, varscan2
- TRIP11 | c.4430C>G p.T1477R | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as COSV50936943; called by muse, mutect2
- TTN | c.42269G>A p.R14090H (on ENST00000591111; = p.R6666H on NM_003319.4) | Missense Mutation (SNP) | VAF 24/146 reads (16%) | PolyPhen probably damaging (0.998); catalogued as rs373613871; called by muse, mutect2, varscan2
- UBE3A | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 5/115 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99217739; called by muse, mutect2
- UNC5C | c.1778G>T p.S593I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV71661107; called by muse, mutect2
- VAV1 | c.1731+1G>A p.X577_splice | Splice Site (SNP) | VAF 31/106 reads (29%) | catalogued as COSV58387306; called by muse, mutect2, varscan2
- VAV3 | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV58386820; called by muse, mutect2
- XIRP2 | c.1660G>T p.V554F (on ENST00000628543; = p.V729F on NM_152381.6) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370504310, COSV54715991; called by muse, mutect2, varscan2
- ZFHX4 | c.5876T>G p.L1959R | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51471130; called by muse, mutect2
- ZNF160 | c.2193dup p.P732Tfs*5 | Frame Shift Ins (INS) | VAF 17/153 reads (11%) | catalogued as rs745909467; called by mutect2, pindel, varscan2
- ZNF208 | c.1175C>A p.T392N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as rs1388341031, COSV68109662; called by muse, mutect2, varscan2
- ZNF521 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 27/286 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64123488, COSV64123670; called by muse, mutect2
- ZSCAN30 | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54351428, COSV54351448; called by muse, mutect2
- CCL5 | c.240G>C p.W80C | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HBP1 | c.1298del p.K433Sfs*6 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.5279dup p.I1761Nfs*18 | Frame Shift Ins (INS) | VAF 16/84 reads (19%) | called by mutect2, pindel, varscan2
- ADGRL4 | c.1317G>A p.L439= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs772300869, COSV66063076; called by muse, mutect2, varscan2
- BLNK | c.462G>A p.P154= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as rs149698554, COSV56410644; called by muse, mutect2, varscan2
- CCPG1 | c.2037G>A p.Q679= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV51242776; called by muse, mutect2, varscan2
- CYREN | c.180G>A p.E60= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs769143112, COSV51966588; called by muse, mutect2, varscan2
- DNAJC22 | c.474C>T p.A158= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as rs770860992, COSV67712464; called by muse, mutect2, varscan2
- DNAJC5B | c.249C>T p.Y83= | Silent (SNP) | VAF 21/246 reads (9%) | catalogued as rs966644862, COSV52537380; called by muse, mutect2
- DPP10 | c.1479T>C p.C493= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV59702123; called by muse, mutect2, varscan2
- ECH1 | c.285G>A p.K95= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV55489707, COSV99669654, COSV99669699; called by muse, mutect2, varscan2
- EEF1A2 | c.387G>A p.K129= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs754118857, COSV53207116, COSV53207292; called by muse, mutect2, varscan2
- EPG5 | c.7092G>A p.Q2364= | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as COSV56352551; called by muse, mutect2
- GFAP | c.1281G>A p.P427= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs759780087, COSV99493235, COSV99493554; called by muse, mutect2, varscan2
- IMPDH1 | c.687C>T p.N229= (on ENST00000470772 / NM_001142573.2; = p.N315= on NM_000883.4) | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as rs1042253, COSV58315135, COSV58317118; called by muse, mutect2
- ITGA9 | c.2955C>T p.I985= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV53247332; called by muse, mutect2
- ITIH2 | c.594C>T p.I198= | Silent (SNP) | VAF 28/159 reads (18%) | catalogued as COSV64434162; called by muse, mutect2, varscan2
- KLHL18 | c.1074G>A p.P358= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs376304909, COSV51747099; called by muse, mutect2, varscan2
- KNDC1 | c.3090C>T p.F1030= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs572650007, COSV58833931; called by muse, mutect2, varscan2
- LAP3 | c.1542C>T p.F514= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV56900734; called by muse, mutect2, varscan2
- MFAP3L | c.423C>T p.R141= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as rs754281347, COSV64372009; called by muse, mutect2, varscan2
- OR13D1 | c.561C>A p.T187= | Silent (SNP) | VAF 55/170 reads (32%) | catalogued as COSV59514330; called by muse, mutect2, varscan2
- OR51M1 | c.33C>T p.F11= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as rs1367075906, COSV100150194, COSV60784985; called by muse, mutect2, varscan2
- PCDHA12 | c.1671C>T p.D557= | Silent (SNP) | VAF 6/146 reads (4%) | catalogued as COSV56495782; called by muse, mutect2
- PDE7A | c.1329C>T p.H443= (on ENST00000401827 / NM_001242318.3; = p.H417= on NM_002603.4) | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs143063031; called by muse, mutect2, varscan2
- PTPRN2 | c.1692C>T p.N564= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs752265596, COSV67049358; called by muse, mutect2, varscan2
- RAB40A | c.639G>A p.P213= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs759711797, COSV58491677; called by muse, mutect2, varscan2
- RABGAP1L | c.1791A>T p.G597= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as COSV52309080; called by muse, mutect2
- RALYL | c.819G>C p.G273= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as COSV101569579; called by muse, mutect2
- RP1 | c.639C>T p.I213= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs267601948, COSV55121216; called by muse, mutect2, varscan2
- RUNX1 | c.843C>T p.S281= (on ENST00000344691 / NM_001001890.3; = p.S308= on NM_001754.5) | Silent (SNP) | VAF 11/130 reads (8%) | catalogued as rs1060504666, COSV55883500; ClinVar: likely benign; called by muse, mutect2
- SALL4 | c.1137C>T p.L379= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV53854153; called by muse, mutect2
- SERPINA1 | c.831C>T p.F277= | Silent (SNP) | VAF 5/91 reads (5%) | catalogued as COSV63345967; called by muse, mutect2
- SLC26A7 | c.975T>C p.A325= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as rs768349832, COSV52598401; called by muse, mutect2, varscan2
- SYT12 | c.384C>G p.L128= | Silent (SNP) | VAF 4/69 reads (6%) | catalogued as COSV101210995; called by muse, mutect2
- TRIM55 | c.531C>T p.A177= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV52548170; called by muse, mutect2, varscan2
- TTF2 | c.1194C>T p.A398= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs370517777; called by muse, mutect2, varscan2
- WDR64 | c.3078T>A p.L1026= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV63797846; called by muse, mutect2, varscan2
- ZNF217 | c.1542G>A p.L514= | Silent (SNP) | VAF 6/137 reads (4%) | catalogued as COSV100184688; called by muse, mutect2
